Somatic mutation profile of tumor specimen C3L-05571-03 (aliquot CPT0275270009) from CPTAC case C3L-05571, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage IIIC1; Tumor grade: G3; Age at diagnosis: 58.1 years (21,214 days).
Specimen C3L-05571-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17ec36a1-8ab2-4fa6-9f2c-a6ed9691a1bb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05571-31 (Blood Derived Normal), aliquot CPT0273520002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5923c2c8-0e7f-4d48-a08b-758f2db0d02c

The open-access MAF lists 49 somatic variants for this specimen: 33 protein-altering or splice-affecting, 6 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 6, Frame Shift Del 3, Intron 3, Nonsense Mutation 3, 3'Flank 2, 5'UTR 2, RNA 1, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1625A>G p.E542G | Missense Mutation (SNP) | VAF 38/103 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen benign (0.221); catalogued as rs1057519927, COSV55876800, COSV55881194, COSV55893680; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 185/346 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ALK | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 22/351 reads (6%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.997); catalogued as rs572340007, COSV66557726, COSV66593660, COSV66594689; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2
- CDH11 | c.739G>A p.G247R | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51760198; called by muse, mutect2, varscan2
- EVPL | c.4696C>T p.R1566W | Missense Mutation (SNP) | VAF 113/378 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs753898829; called by muse, mutect2, varscan2
- FAM90A1 | c.718G>A p.V240I | Missense Mutation (SNP) | VAF 56/842 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs779014663; called by muse, mutect2
- ICAM5 | c.790C>A p.L264I | Missense Mutation (SNP) | VAF 56/481 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1410045913; called by muse, mutect2, varscan2
- IVL | c.1041G>T p.E347D | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.078); catalogued as rs1392532751; called by muse, mutect2, varscan2
- PCDHA10 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 119/483 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV56481854; called by muse, mutect2, varscan2
- PLCL1 | c.1324G>A p.V442I | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.05); catalogued as rs201197388; called by muse, mutect2, varscan2
- TAF1 | c.2927G>C p.R976P (on ENST00000373790 / NM_138923.4; = p.R997P on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52110734; called by muse, mutect2, varscan2
- WEE1 | c.166C>T p.Q56* | Nonsense Mutation (SNP) | VAF 5/32 reads (16%) | catalogued as COSV55197695; called by muse, mutect2
- ARHGAP35 | c.1095del p.A366Pfs*5 | Frame Shift Del (DEL) | VAF 76/214 reads (36%) | called by mutect2, pindel, varscan2
- ARHGAP40 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- BMF | c.427C>T p.Q143* | Nonsense Mutation (SNP) | VAF 37/158 reads (23%) | called by muse, mutect2, varscan2
- CACNG2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 213/303 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CELSR3 | c.3632A>T p.E1211V | Missense Mutation (SNP) | VAF 40/537 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.041); called by muse, mutect2
- DCHS1 | c.3340G>T p.V1114L | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.97); called by muse, mutect2
- DPYD | c.1957C>T p.L653F | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EXPH5 | c.2377A>G p.K793E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- FAAP100 | c.2443C>G p.Q815E | Missense Mutation (SNP) | VAF 87/324 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- GALR1 | c.130T>C p.F44L | Missense Mutation (SNP) | VAF 17/444 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2
- LRRN3 | c.353T>A p.L118H | Missense Mutation (SNP) | VAF 15/152 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- OR4X2 | c.710C>A p.A237D | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- OR6K6 | c.73A>G p.M25V (on ENST00000368144; = p.M1? on NM_001005184.1) | Missense Mutation (SNP) | VAF 13/193 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- PCDHB3 | c.2082G>C p.L694F | Missense Mutation (SNP) | VAF 83/524 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POSTN | c.20T>A p.M7K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRPF4B | c.2200G>C p.E734Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SLC38A8 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 17/149 reads (11%) | called by muse, mutect2, varscan2
- SRPX | c.1181T>A p.I394N | Missense Mutation (SNP) | VAF 58/260 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- USP24 | c.525del p.F175Lfs*14 | Frame Shift Del (DEL) | VAF 34/145 reads (23%) | called by mutect2, pindel, varscan2
- VRK1 | c.974dup p.L325Ffs*10 | Frame Shift Ins (INS) | VAF 29/124 reads (23%) | called by mutect2, pindel, varscan2
- ZXDA | c.2345del p.G782Vfs*11 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by mutect2, varscan2
- CACNA1S | c.2235C>T p.D745= | Silent (SNP) | VAF 68/403 reads (17%) | catalogued as rs754971473, COSV62942083; called by muse, mutect2, varscan2
- CRB1 | c.2931A>G p.T977= | Silent (SNP) | VAF 25/131 reads (19%) | catalogued as rs764177876; called by muse, mutect2, varscan2
- KIF1A | c.15G>C p.S5= | Silent (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- KLC1 | c.747C>T p.H249= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs113655798, COSV55805594; called by muse, mutect2
- WASF1 | c.636G>A p.E212= | Silent (SNP) | VAF 15/302 reads (5%) | called by muse, mutect2
- ZIC3 | c.345G>A p.T115= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as COSV54975609; called by muse, mutect2
- CCBE1 | c.554-105G>T | Intron (SNP) | VAF 45/149 reads (30%) | catalogued as rs759125640; called by muse, mutect2, varscan2
- CCL20 | c.-6A>G | 5'UTR (SNP) | VAF 51/172 reads (30%) | catalogued as rs779095378; called by muse, mutect2, varscan2
- KANSL1L | c.2029+90G>A | Intron (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- MIR6859-3 | chr15:101973956 G>A | 3'Flank (SNP) | VAF 28/522 reads (5%) | called by muse, mutect2
- MST1L | n.1367_1377del | RNA (DEL) | VAF 54/530 reads (10%) | called by pindel, varscan2
- MYH11 | c.*25C>T | 3'UTR (SNP) | VAF 110/397 reads (28%) | catalogued as rs753223174, COSV100260285; called by muse, mutect2, varscan2
- PRR12 | chr19:49594984 G>A | 5'Flank (SNP) | VAF 84/210 reads (40%) | called by muse, mutect2, varscan2
- RAN | c.-493G>T | 5'UTR (SNP) | VAF 17/136 reads (13%) | called by muse, mutect2, varscan2
- RGL1 | chr1:183930276 G>A | 3'Flank (SNP) | VAF 21/300 reads (7%) | catalogued as rs1315998818; called by muse, mutect2
- TMEM241 | c.383+790G>A | Intron (SNP) | VAF 12/312 reads (4%) | catalogued as rs923054260; called by muse, mutect2
